Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0MA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0MA-01A (Primary Tumor).

100-0-3

adenocarcinoma, endometrioid, Nax 8380/3

Site: endometrium 054.1 for 5/3/11

FINAL DIAGNOSIS:

**PART 1: SKIN, "MOLE", EXCISION –
CAPILLARY HEMANGIOMA WITH SCLEROSIS.**

**PART 2: UTERUS AND BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-
OOPHORECTOMY (196 GRAMS) –**

- A. POORLY DIFFERENTIATED ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE WITH EXTENSIVE SQUAMOUS DIFFERENTIATION AND NECROSIS, GRADE 3, STAGE 1C (see comment).
- B. THE TUMOR INVADES APPROXIMATELY 78% OF THE MYOMETRIAL THICKNESS (2.5 CM INVASION OF 3.2 CM MYOMETRIUM).
- C. THE TUMOR INVOLVES 60% OF THE ENDOMETRIAL SURFACE.
- D. CERVIX, NEGATIVE FOR TUMOR.
- E. THE TUMOR INVOLVES BOTH ANTERIOR AND POSTERIOR LOWER UTERINE SEGMENTS.
- F. EXTENSIVE LYMPHOVASCULAR SPACE INVASION IS PRESENT.
- G. LEIOMYOMA (0.9 CM).
- H. RIGHT OVARY WITH CALCIFIED FIBROMAS, 0.9 AND 0.5 CM, WITH FOCAL OSSEOUS METAPLASIA.
- I. LEFT OVARY WITH PHYSIOLOGIC CHANGES, SEROSAL ADHESIONS AND EPITHELIAL INCLUSIONS.
- J. RIGHT FALLOPIAN TUBE NEGATIVE FOR TUMOR.
- K. LEFT FALLOPIAN TUBE WITH WALTHARD NESTS, NEGATIVE FOR TUMOR.

**PART 3: LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION –
THREE LYMPH NODES, FREE OF METASTATIC CARCINOMA (0/3) (see comment).**

**PART 4: LYMPH NODES, RIGHT OBTURATOR, EXCISION –
ONE LYMPH NODE, FREE OF METASTATIC CARCINOMA (0/1).**

**PART 5: LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION –
THREE LYMPH NODES, FREE OF METASTATIC CARCINOMA (0/3) (see comment).**

**PART 6: LYMPH NODES, LEFT OBTURATOR, EXCISION –
ONE LYMPH NODE, FREE OF METASTATIC CARCINOMA (0/1).**

**PART 7: LYMPH NODES, RIGHT COMMON, EXCISION –
ONE LYMPH NODE, FREE OF METASTATIC CARCINOMA (0/1).**

**PART 8: LYMPH NODES, RIGHT PARAAORTIC, EXCISION –
FOUR LYMPH NODES, FREE OF METASTATIC CARCINOMA (0/4).**

**PART 9: LYMPH NODES, LEFT COMMON, EXCISION –
ONE LYMPH NODE, FREE OF METASTATIC CARCINOMA (0/1) (see comment).**

**PART 10: LYMPH NODES, LEFT PARAAORTIC, EXCISION –
TWO LYMPH NODES, FREE OF METASTATIC CARCINOMA (0/2).**

COMMENT:

The tumor has a focal well-differentiated component confined to a polyp but is otherwise composed of solid sheets of endometrioid adenocarcinoma, FIGO grade 3.

Immunostains performed on parts 3, 5, and 9 confirm the absence of lymph node metastases (see microscopic description for details).

Immunostaining for D2-40 and CD34 confirms the presence of lymphovascular invasion.

Companion pelvic wash cytology is negative for malignant cells

HORMONE RECEPTOR IMMUNOHISTOCHEMISTRY

**ESTROGEN
PROGESTERONE**

RESULT
NEGATIVE IN ENDOMETRIAL ADENOCARCINOMA
NEGATIVE IN ENDOMETRIAL ADENOCARCINOMA

Source: NCI Genomic Data Commons file 5771613d-dc1c-46d4-b6d8-c6c89c50163b (TCGA-BG-A0MA.E5908692-5B04-407B-818A-D202756DD880.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).